Somatic mutation profile of tumor specimen TCGA-56-A4ZJ-01A (aliquot TCGA-56-A4ZJ-01A-11D-A25L-08) from TCGA case TCGA-56-A4ZJ, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 75.3 years (27,516 days).
Specimen TCGA-56-A4ZJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95bb23ef-d549-498b-a9d7-77d2d2b74702.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-A4ZJ-10A (Blood Derived Normal), aliquot TCGA-56-A4ZJ-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab0c9bd7-6acc-4d34-a002-635622bb8378

The open-access MAF lists 97 somatic variants for this specimen: 74 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 65, Silent 23, Nonsense Mutation 7, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL7B | c.580G>T p.G194W | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101012480, COSV101012601; called by muse, mutect2, varscan2
- ADAMTS4 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs1242506429, COSV100917463; called by muse, mutect2
- ADGRE2 | c.660G>T p.Q220H | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV100216067; called by muse, mutect2
- AFF1 | c.283A>G p.I95V | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.182); catalogued as COSV100320639; called by muse, mutect2
- ALMS1 | c.9065A>T p.Q3022L | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100042539; called by muse, mutect2
- ANKMY2 | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as rs750492927, COSV100187102; called by muse, mutect2
- ASPM | c.7691A>T p.Y2564F | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.656); catalogued as COSV54132526, COSV99660413; called by muse, mutect2
- BEST3 | c.417C>G p.I139M | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV56994431, COSV99876226; called by muse, mutect2, varscan2
- C1orf50 | c.352A>T p.N118Y | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV100998109; called by muse, mutect2
- CDH10 | c.1142C>A p.P381H | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV52601151, COSV52601616; called by muse, mutect2
- CENPI | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99515428; called by muse, mutect2
- CENPI | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99515431; called by muse, mutect2
- CILK1 | c.701T>A p.M234K | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100607752; called by muse, mutect2
- CKAP2 | c.503C>G p.A168G (on ENST00000378037 / NM_001098525.2; = p.A167G on NM_018204.5) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs1457375103, COSV99318289; called by muse, mutect2
- COL8A1 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV53732874, COSV99657798; called by muse, mutect2, varscan2
- DDC | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100779382; called by muse, mutect2, varscan2
- DLC1 | c.3326A>T p.Q1109L (on ENST00000276297 / NM_001348081.2; = p.Q672L on NM_006094.5) | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV99363275; called by muse, mutect2
- DOCK10 | c.4312T>C p.S1438P | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.869); catalogued as COSV99289646; called by muse, mutect2
- FAM155A | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as COSV101028164; called by muse, mutect2, varscan2
- GLRA2 | c.156G>T p.M52I | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.708); catalogued as COSV99490954; called by muse, mutect2
- GLRA2 | c.157G>T p.G53* | Nonsense Mutation (SNP) | VAF 16/176 reads (9%) | catalogued as COSV99491104; called by muse, mutect2
- GRIA3 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99990269; called by muse, mutect2
- GRIPAP1 | c.2185-2A>C p.X729_splice | Splice Site (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99501997; called by muse, mutect2, varscan2
- IRS1 | c.1312T>G p.F438V | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.437); catalogued as COSV100524563; called by muse, mutect2
- KCNB2 | c.43A>G p.R15G | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs375433681; called by muse, mutect2, varscan2
- KCNV1 | c.1156G>T p.A386S | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52085185, COSV99819123; called by muse, mutect2, varscan2
- KDM4B | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769295777, COSV50208548; called by muse, mutect2
- KIF7 | c.2516A>G p.Q839R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV101067649; called by muse, mutect2, varscan2
- KLHL1 | c.1297G>T p.A433S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV64777711; called by muse, mutect2
- LHCGR | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.699); catalogued as COSV99683742; called by muse, mutect2
- LRRC43 | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV99928228; called by muse, mutect2, varscan2
- LRRC8B | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100446545; called by muse, mutect2
- MBL2 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100906350, COSV64758231; called by muse, mutect2, varscan2
- MCCC1 | c.1266A>T p.Q422H | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99659729; called by muse, mutect2, varscan2
- MRC1 | c.1919C>T p.T640M | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs970799233; called by muse, mutect2
- NCAPG2 | c.268A>T p.R90* | Nonsense Mutation (SNP) | VAF 16/96 reads (17%) | catalogued as COSV99317036; called by muse, mutect2
- ODC1 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1431038346, COSV99301290; called by muse, mutect2
- OPHN1 | c.2161G>T p.D721Y | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV100830458, COSV62787266; called by muse, mutect2, varscan2
- OPHN1 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 13/155 reads (8%) | catalogued as COSV100830460; called by muse, mutect2
- OR10S1 | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV101602476; called by muse, mutect2
- OR10S1 | c.374A>G p.E125G | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV101602477; called by muse, mutect2, varscan2
- OR5D18 | c.322T>A p.F108I | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV100450713; called by muse, mutect2, varscan2
- OR5H14 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101454188, COSV71193926; called by muse, mutect2
- OR5H6 | c.646T>C p.F216L (on ENST00000642105; = p.F200L on NM_001005479.2) | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.327); catalogued as rs777105136, COSV101051778, COSV67352110; called by muse, mutect2, varscan2
- PDZD2 | c.5489C>T p.P1830L | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV99225094; called by muse, mutect2, varscan2
- POLA1 | c.4035G>T p.W1345C | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100985476; called by muse, mutect2
- PREX2 | c.2786A>G p.H929R | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.109); catalogued as COSV55783225; called by muse, mutect2, varscan2
- PRF1 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100942618; called by muse, mutect2, varscan2
- PRG2 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 16/114 reads (14%) | catalogued as COSV100314924; called by muse, mutect2, varscan2
- PTCHD1 | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV101037696; called by muse, mutect2
- RBM41 | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.018); catalogued as rs1187995340, COSV99179796; called by muse, mutect2
- RIPOR3 | c.1918A>T p.N640Y | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV99246532; called by muse, mutect2, varscan2
- RPS6KA3 | c.2164G>A p.G722S | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV101084402; called by muse, mutect2
- RPS6KA6 | c.1984C>A p.H662N | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.281); catalogued as COSV99424784; called by muse, mutect2
- RTTN | c.2678A>G p.E893G | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99732526; called by muse, mutect2, varscan2
- RXRG | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1383178968, COSV100717570; called by muse, mutect2
- SLC4A3 | c.3526G>T p.A1176S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.03); catalogued as COSV99812869; called by muse, mutect2
- SLC5A8 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 21/314 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as rs200408412, COSV101610541; called by muse, mutect2
- SLC6A15 | c.1159G>C p.D387H | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV99880855; called by muse, mutect2, varscan2
- SSX5 | c.203C>G p.P68R (on ENST00000347757 / NM_175723.1; = p.P109R on NM_021015.4) | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs782208422, COSV100308767; called by muse, mutect2
- TEC | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.37); catalogued as COSV67404292; called by muse, mutect2
- TENM1 | c.7935C>A p.H2645Q | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV100950103; called by muse, mutect2
- TENM1 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs746516649, COSV100949136, COSV64439371; called by muse, mutect2
- TSHR | c.1729C>A p.P577T | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.047); catalogued as COSV99991914; called by muse, mutect2, varscan2
- UBAP2 | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.986); catalogued as COSV100671446; called by muse, mutect2, varscan2
- UMPS | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99229050; called by muse, varscan2
- USP26 | c.1106C>A p.S369* | Nonsense Mutation (SNP) | VAF 18/182 reads (10%) | catalogued as COSV63708217, COSV63708421; called by muse, mutect2, varscan2
- XIRP2 | c.7942C>A p.Q2648K (on ENST00000628543; = p.Q2823K on NM_152381.6) | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99743205; called by muse, mutect2, varscan2
- ZNF140 | c.1195T>A p.S399T | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.113); catalogued as COSV100166837; called by muse, mutect2
- ZNF721 | c.1824A>C p.K608N (on ENST00000338977; = p.K620N on NM_133474.4) | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100167418; called by muse, mutect2
- ZNF804B | c.3640C>A p.L1214M | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV100303958; called by muse, mutect2
- CEP192 | c.4390dup p.S1464Ffs*9 | Frame Shift Ins (INS) | VAF 17/152 reads (11%) | called by mutect2, pindel, varscan2
- HABP2 | c.684C>G p.Y228* | Nonsense Mutation (SNP) | VAF 8/121 reads (7%) | called by muse, mutect2
- RPS9 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.228); called by muse, mutect2
- AFTPH | c.2205C>G p.T735= | Silent (SNP) | VAF 13/124 reads (10%) | catalogued as COSV99480785; called by muse, mutect2, varscan2
- ASIC5 | c.1125T>C p.V375= | Silent (SNP) | VAF 8/131 reads (6%) | catalogued as COSV101611141; called by muse, mutect2
- AWAT1 | c.498G>C p.L166= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100997204; called by muse, mutect2
- CEACAM7 | c.90G>A p.L30= | Silent (SNP) | VAF 11/129 reads (9%) | catalogued as rs1555811325, COSV99137238; called by muse, mutect2
- CES1 | c.189G>T p.L63= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV100828684; called by muse, mutect2
- GABRR2 | c.804A>G p.T268= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV101298969; called by muse, varscan2
- H3C8 | c.315T>C p.F105= | Silent (SNP) | VAF 13/150 reads (9%) | catalogued as rs768298221, COSV100010149; called by muse, mutect2
- HCN1 | c.1731A>T p.P577= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as COSV100300370; called by muse, mutect2, varscan2
- IQGAP2 | c.3825G>A p.K1275= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99167338; called by muse, mutect2
- KCNS2 | c.495C>A p.P165= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs754306840, COSV54639222; called by mutect2, varscan2
- MID2 | c.1797C>T p.S599= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV53310762, COSV99464416; called by muse, mutect2
- MORC4 | c.1719G>T p.V573= | Silent (SNP) | VAF 16/195 reads (8%) | catalogued as COSV99717233; called by muse, mutect2
- NMUR2 | c.63A>T p.P21= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV99676922; called by muse, mutect2
- NXNL1 | c.312G>A p.E104= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs1209762822, COSV100112004, COSV57324726; called by muse, mutect2, varscan2
- OR7G3 | c.525C>A p.P175= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as COSV100555606, COSV59640515; called by muse, mutect2
- PTPN11 | c.1494G>T p.R498= | Silent (SNP) | VAF 21/221 reads (10%) | catalogued as rs1190463676, COSV100692687; called by muse, mutect2
- ROPN1B | c.477C>T p.S159= | Silent (SNP) | VAF 26/173 reads (15%) | catalogued as COSV99305583; called by muse, mutect2, varscan2
- SLC10A2 | c.81T>C p.N27= | Silent (SNP) | VAF 8/148 reads (5%) | catalogued as COSV99807989; called by muse, mutect2
- SLC6A5 | c.1665C>G p.T555= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100116914; called by muse, mutect2, varscan2
- SPIRE2 | c.900G>A p.G300= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs758815410, COSV100988841; called by muse, mutect2, varscan2
- TNRC18 | c.8265C>T p.V2755= | Silent (SNP) | VAF 9/131 reads (7%) | catalogued as rs1413032413, COSV100078858; called by muse, mutect2
- TPI1 | c.465G>C p.L155= (on ENST00000229270; = p.L118= on NM_000365.6) | Silent (SNP) | VAF 16/408 reads (4%) | catalogued as COSV99222901; called by muse, mutect2
- VPS13B | c.9825A>G p.P3275= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs764864362, COSV62132395; called by mutect2, varscan2
